Somatic mutation profile of tumor specimen 9452572f-e3ec-4063-a82e-43ac90 (aliquot 9452572f-e3ec-4063-a82e-43ac90_D6) from CPTAC case 01CO008, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 9452572f-e3ec-4063-a82e-43ac90: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 839d4aa8-457a-45d6-bf66-2e5eb89ad48b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0c1f2419-4b8a-42f7-a369-a5b438 (Blood Derived Normal), aliquot 0c1f2419-4b8a-42f7-a369-a5b438_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dfde7ed-680d-4235-a4f6-e792a8cd5222

The open-access MAF lists 192 somatic variants for this specimen: 126 protein-altering or splice-affecting, 46 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 46, Intron 12, Nonsense Mutation 10, Frame Shift Del 4, 3'UTR 3, RNA 2, 5'UTR 2, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1926del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 45/196 reads (23%) | hotspot (GDC flag); catalogued as COSV60103774; called by pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 112/291 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MED17 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780394, COSV99315614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57171912; called by muse, mutect2, varscan2
- ACTR5 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs1268021889; called by muse, mutect2, varscan2
- ADCY6 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs183886636, COSV57170282; called by muse, mutect2, varscan2
- AGTR1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767462753, COSV100836971; called by muse, mutect2, varscan2
- AMBN | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753263140; called by muse, mutect2, varscan2
- ANKH | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs776803043; called by muse, mutect2, varscan2
- APEX2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141646629, COSV100895225; called by muse, mutect2, varscan2
- ATP2B1 | c.3524G>A p.R1175H | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as rs752708878; called by muse, mutect2, varscan2
- AUTS2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750187638; called by muse, mutect2, varscan2
- BIRC6 | c.9499G>A p.G3167S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV101428514; called by muse, mutect2, varscan2
- C3 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs945676974, COSV55573557; called by muse, mutect2, varscan2
- CA9 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768211018; called by muse, mutect2, varscan2
- CAPRIN2 | c.2623A>C p.K875Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99195402; called by muse, mutect2, varscan2
- CCDC183 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376681775; called by mutect2, varscan2
- CFAP65 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0.02); catalogued as rs376689400, COSV55392313; called by muse, mutect2, varscan2
- COL22A1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200816628, COSV100280467, COSV57327951; called by muse, mutect2, varscan2
- CPEB3 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV99798253; called by muse, varscan2
- CSMD1 | c.5888G>A p.R1963H (on ENST00000520002; = p.R1962H on NM_033225.6) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057015722, COSV59325348; called by muse, mutect2, varscan2
- CYP2A6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1355151029, COSV56537500; called by muse, mutect2, varscan2
- DLGAP2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs58497511; called by muse, mutect2
- ERBB3 | c.2908C>T p.R970* | Nonsense Mutation (SNP) | VAF 185/512 reads (36%) | catalogued as rs768736698; called by muse, mutect2, varscan2
- FAM155B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV52936070; called by muse, mutect2, varscan2
- FERD3L | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs752444969, COSV51761506; called by muse, mutect2, varscan2
- FLT4 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 144/435 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001159, CM032231, COSV56108343, COSV56115160; called by muse, mutect2, varscan2
- GAS2L3 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as rs1395543300; called by muse, mutect2, varscan2
- HELZ2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1377953557; called by muse, mutect2
- HTRA3 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs375160977, COSV100246241; called by muse, mutect2, varscan2
- IGFBP3 | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 40/206 reads (19%) | catalogued as COSV51872748; called by muse, mutect2, varscan2
- IL12RB1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs377441024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 102/489 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as rs373645838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2B | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52127254, COSV99276407; called by muse, mutect2, varscan2
- KIR3DL2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 80/478 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs750152740, COSV54393896; called by muse, varscan2
- KRT83 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs768058853; called by muse, mutect2, varscan2
- MAPK8 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs755894470, COSV64408280; called by muse, mutect2, varscan2
- MASP1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs754485637, COSV56225321; called by muse, mutect2, varscan2
- NKD1 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750832456, COSV99193993; called by muse, mutect2, varscan2
- P3R3URF-PIK3R3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 34/188 reads (18%) | PolyPhen benign (0); catalogued as rs547237837; called by muse, mutect2, varscan2
- PABPC5 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs921534308; called by muse, mutect2, varscan2
- PCDH10 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as rs577486596; called by muse, mutect2, varscan2
- PCDH18 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61266304; called by muse, mutect2, varscan2
- PCDHA1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 134/799 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs782171982, COSV65373166; called by muse, mutect2, varscan2
- PCDHB15 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 84/849 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1359917718, COSV51203582; called by muse, mutect2, varscan2
- PCDHB5 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 92/555 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV50653087, COSV50669649; called by muse, mutect2, varscan2
- PDHA2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs372154327; called by muse, mutect2, varscan2
- PKP3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1484468177, COSV58986364; called by muse, mutect2, varscan2
- PROP1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs368561632, COSV57644705; called by muse, mutect2, varscan2
- PRPF19 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.919); catalogued as COSV99920557; called by muse, mutect2, varscan2
- PTPRT | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1358914349, COSV61986580; called by muse, mutect2, varscan2
- RAD52 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs368534549; called by muse, mutect2, varscan2
- RBPMS2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs188576967; called by muse, mutect2, varscan2
- SALL3 | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs149417255; called by muse, mutect2, varscan2
- SCN10A | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs148851890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDE2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as rs1275642431; called by muse, mutect2, varscan2
- SEC14L5 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs767906101, COSV52041749; called by muse, mutect2, varscan2
- SETDB1 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 216/402 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54979818; called by muse, mutect2, varscan2
- SIGLEC1 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.836); catalogued as rs373105785; called by muse, mutect2, varscan2
- SLC6A11 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs183457681; called by muse, mutect2, varscan2
- SMARCA2 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs774448114; called by muse, mutect2, varscan2
- SMOC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs749505789, COSV62760239; called by muse, mutect2
- SPATA31D1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 104/361 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs267602287, COSV61193328; called by muse, mutect2, varscan2
- TCTE1 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as rs535748958, COSV65255273; called by muse, mutect2, varscan2
- USH1G | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58880848; called by muse, mutect2, varscan2
- USH2A | c.3005G>T p.C1002F | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382537, COSV56407555; called by muse, mutect2, varscan2
- USP5 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1555129412; called by muse, mutect2, varscan2
- WDR49 | c.1268C>A p.S423* (on ENST00000308378 / NM_001366158.1; = p.S764* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV57705394, COSV57708425; called by muse, mutect2, varscan2
- WNT11 | c.541dup p.T181Nfs*7 | Frame Shift Ins (INS) | VAF 35/128 reads (27%) | catalogued as rs1320348614; called by mutect2, varscan2
- ZBTB22 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV56471924; called by muse, mutect2, varscan2
- ZBTB32 | c.760T>C p.W254R | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs752952764; called by muse, mutect2, varscan2
- ZNF317 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs756065175; called by muse, mutect2, varscan2
- ZNF569 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV100386409; called by muse, mutect2, varscan2
- ABI1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by mutect2, varscan2
- ARFGEF2 | c.3148A>C p.K1050Q | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B3 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 89/504 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEST1 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC6 | c.10540C>A p.P3514T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BSN | c.9569A>G p.E3190G | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C4orf54 | c.1319A>T p.N440I | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CFH | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 50/284 reads (18%) | called by muse, mutect2, varscan2
- CFP | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CREBZF | c.886T>A p.F296I | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- CRPPA | c.1313A>C p.K438T (on ENST00000407010 / NM_001368197.1; = p.K388T on NM_001101417.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DOCK4 | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FAM184A | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM47A | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 19/230 reads (8%) | called by muse, mutect2
- FAM76A | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); called by muse, varscan2
- FASTKD2 | c.2059A>G p.T687A | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN1 | c.8280G>T p.K2760N | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GAS7 | c.401C>T p.A134V (on ENST00000432992 / NM_201433.2; = p.A74V on NM_201432.2) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBX1 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GGACT | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GOLM2 | c.442A>T p.R148W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPC4 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GRM1 | c.2126T>A p.I709N | Missense Mutation (SNP) | VAF 130/350 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP10 | c.842A>C p.D281A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HLTF | c.1526A>T p.Y509F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIF15 | c.2499C>A p.N833K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRT33A | c.875del p.L292Rfs*9 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | called by mutect2, pindel, varscan2
- LGI4 | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MROH5 | c.1409G>C p.S470T | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEUROD4 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.045); called by mutect2, varscan2
- NKX2-6 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8G2P | c.764C>A p.A255E | Missense Mutation (SNP) | VAF 69/309 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAFAH1B1 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH12 | c.2992G>T p.D998Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PCDHA8 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 180/708 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); called by muse, varscan2
- PDGFD | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHACTR3 | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- PIEZO2 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- PRM3 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 62/334 reads (19%) | called by muse, mutect2, varscan2
- RBFOX3 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SELENBP1 | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SETX | c.1603T>A p.Y535N | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT6H | c.1349+1G>A p.X450_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- SWAP70 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- SYNPR | c.596del p.K199Rfs*91 | Frame Shift Del (DEL) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- TAOK1 | c.1926_1927del p.Q642Hfs*15 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- TENM1 | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TEPP | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YLPM1 | c.2221T>A p.S741T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZMYM1 | c.2890A>G p.K964E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF274 | c.302C>A p.A101D (on ENST00000610905; = p.A69D on NM_016325.3) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZNF530 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- A2ML1 | c.4182T>A p.V1394= | Silent (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2, varscan2
- AOC2 | c.1776G>A p.A592= | Silent (SNP) | VAF 135/286 reads (47%) | catalogued as rs150869522; called by muse, mutect2, varscan2
- AR | c.1674G>A p.K558= | Silent (SNP) | VAF 61/357 reads (17%) | catalogued as rs770563263; called by muse, mutect2, varscan2
- ATM | c.6027C>T p.Y2009= | Silent (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- C10orf71 | c.3345C>T p.H1115= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs1321977503; called by muse, mutect2, varscan2
- C4orf54 | c.1962C>T p.S654= | Silent (SNP) | VAF 112/344 reads (33%) | called by muse, mutect2, varscan2
- DEFB123 | c.90C>A p.G30= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- DMP1 | c.204C>T p.D68= | Silent (SNP) | VAF 75/268 reads (28%) | catalogued as rs375708823; called by muse, mutect2, varscan2
- DOC2B | c.600C>T p.Y200= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs528855216, COSV59095121; called by muse, mutect2, varscan2
- ELMO1 | c.531G>T p.S177= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- ESRRG | c.999C>T p.D333= | Silent (SNP) | VAF 129/268 reads (48%) | catalogued as rs186770984; called by muse, mutect2, varscan2
- GRIK1 | c.2055G>A p.S685= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as rs534052204; called by muse, mutect2, varscan2
- HRH2 | c.546C>T p.Y182= | Silent (SNP) | VAF 177/462 reads (38%) | catalogued as rs772344735; called by muse, mutect2, varscan2
- KIR2DL3 | c.360C>T p.I120= | Silent (SNP) | VAF 49/272 reads (18%) | catalogued as rs771556841, COSV60897767; called by muse, mutect2, varscan2
- KRT12 | c.924C>A p.I308= | Silent (SNP) | VAF 199/412 reads (48%) | called by muse, mutect2, varscan2
- KRTAP12-2 | c.231C>G p.P77= | Silent (SNP) | VAF 27/112 reads (24%) | called by mutect2, varscan2
- LRRC4B | c.2121C>T p.N707= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs370057584; called by mutect2, varscan2
- MAGI3 | c.3727C>T p.L1243= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100290135; called by muse, mutect2, varscan2
- MYH1 | c.3453C>T p.S1151= | Silent (SNP) | VAF 81/355 reads (23%) | catalogued as rs886716864; called by muse, mutect2, varscan2
- MYO1A | c.2904C>T p.D968= | Silent (SNP) | VAF 156/482 reads (32%) | catalogued as COSV55658088; called by muse, mutect2, varscan2
- NACAD | c.1281C>T p.S427= | Silent (SNP) | VAF 52/295 reads (18%) | catalogued as rs1195072411; called by muse, mutect2, varscan2
- NCOA3 | c.954C>T p.H318= | Silent (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- NKX2-6 | c.63C>T p.R21= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.939G>A p.A313= | Silent (SNP) | VAF 70/347 reads (20%) | catalogued as COSV52801486; called by muse, mutect2, varscan2
- OR10X1 | c.183C>A p.I61= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs776458184; called by muse, mutect2, varscan2
- POU4F2 | c.879G>A p.S293= | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as COSV99850790; called by muse, mutect2, varscan2
- RPA4 | c.51A>C p.G17= | Silent (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- RTP1 | c.633G>A p.E211= | Silent (SNP) | VAF 54/177 reads (31%) | called by muse, mutect2, varscan2
- RYR1 | c.12582C>T p.F4194= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs753263342; called by muse, mutect2, varscan2
- SBK3 | c.585C>T p.P195= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs766910374; called by muse, mutect2, varscan2
- SELENOV | c.600G>A p.A200= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs1161858092; called by muse, mutect2, varscan2
- SIGLEC12 | c.918G>A p.T306= (on ENST00000291707 / NM_053003.4; = p.T188= on NM_033329.2) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs375071831; called by muse, mutect2, varscan2
- SLC4A5 | c.774C>T p.D258= | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, varscan2
- SLX4 | c.2991G>A p.P997= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as rs770736311, COSV53560721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYPL2 | c.342C>T p.P114= | Silent (SNP) | VAF 25/283 reads (9%) | catalogued as rs767485624, COSV100881570, COSV63994691; called by muse, mutect2
- SYT11 | c.672C>T p.D224= | Silent (SNP) | VAF 47/255 reads (18%) | catalogued as rs751883423, COSV64173634; called by muse, mutect2, varscan2
- TEX13A | c.802C>A p.R268= | Silent (SNP) | VAF 103/612 reads (17%) | catalogued as COSV100781573; called by mutect2, varscan2
- TMEM132D | c.3153C>T p.T1051= | Silent (SNP) | VAF 69/194 reads (36%) | catalogued as rs754161278, COSV101242537; called by muse, mutect2, varscan2
- TRIM7 | c.370C>A p.R124= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- TSPYL5 | c.201C>T p.S67= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs572652851; called by muse, mutect2, varscan2
- TSPYL5 | c.99G>A p.P33= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV59071038; called by muse, mutect2, varscan2
- TTC37 | c.3726T>C p.A1242= | Silent (SNP) | VAF 88/266 reads (33%) | called by muse, mutect2, varscan2
- UNC79 | c.6288G>A p.P2096= (on ENST00000393151 / NM_001346218.2; = p.P1919= on NM_020818.5) | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as rs753101383, COSV56380645; called by muse, mutect2, varscan2
- WFS1 | c.1914G>A p.V638= | Silent (SNP) | VAF 81/398 reads (20%) | catalogued as rs1289862156; called by muse, mutect2, varscan2
- XYLT2 | c.2583C>T p.D861= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs374244169; called by muse, mutect2, varscan2
- ZNF707 | c.870C>T p.C290= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs782506046; called by muse, mutect2, varscan2
- AAK1 | c.*9609C>T | 3'UTR (SNP) | VAF 49/163 reads (30%) | catalogued as rs765778769; called by muse, mutect2, varscan2
- ACADM | c.*41C>T | 3'UTR (SNP) | VAF 15/81 reads (19%) | catalogued as rs1017029118; called by muse, mutect2, varscan2
- BRMS1L | c.143-1595G>T | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- C1orf159 | c.-23+23C>T | Intron (SNP) | VAF 43/95 reads (45%) | catalogued as rs1317591786; called by muse, mutect2, varscan2
- CARNMT1 | c.426+22T>G | Intron (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- CELP | n.2366G>A | RNA (SNP) | VAF 132/434 reads (30%) | called by muse, mutect2, varscan2
- COL1A2 | c.2349+27G>A | Intron (SNP) | VAF 42/151 reads (28%) | catalogued as rs201611266; called by muse, mutect2, varscan2
- DNASE1L1 | c.-136C>T | 5'UTR (SNP) | VAF 44/128 reads (34%) | catalogued as rs782737706; called by muse, mutect2, varscan2
- DZIP1L | c.2142+87G>T | Intron (SNP) | VAF 18/130 reads (14%) | called by muse, varscan2
- FKBP4 | c.106-837T>C | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- KNTC1 | c.5497-64G>C | Intron (SNP) | VAF 23/118 reads (19%) | catalogued as rs1198614195; called by muse, mutect2, varscan2
- MACF1 | c.15832-11578A>G | Intron (SNP) | VAF 105/228 reads (46%) | catalogued as rs1254345926; called by muse, mutect2, varscan2
- MIR9-1HG | n.703C>A | RNA (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2719_18662-2711del | Intron (DEL) | VAF 93/559 reads (17%) | called by mutect2, pindel, varscan2
- PRND | chr20:4732426 G>T | 3'Flank (SNP) | VAF 29/154 reads (19%) | catalogued as rs1194155506; called by muse, mutect2, varscan2
- RYK | c.1182-13T>C | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.-61C>T | 5'UTR (SNP) | VAF 45/172 reads (26%) | catalogued as rs749010685; called by muse, mutect2, varscan2
- ZDHHC23 | c.1041-673C>G | Intron (SNP) | VAF 109/278 reads (39%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3511G>A | Intron (SNP) | VAF 33/134 reads (25%) | catalogued as rs370213262; called by muse, mutect2, varscan2
- ZNF99 | c.*319T>G | 3'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as COSV68054685; called by muse, mutect2
